Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5887, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5887-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Analysis & History:

with partial nephrectomy, now with ipsilateral recurrence.

Specimens Submitted:

1: SP: Lymph nodes, paracaval; excision

2: SP: Kidney, right; total nephrectomy

3: SP: Soft tissue, perinephric; excision

4: SP: Lymph nodes #2, paracaval; excision

DIAGNOSIS:

1. SP: Lymph nodes, paracaval; excision

Lymph Nodes:

Not identified

Benign fibroadipose tissue; no lymph nodes identified in entirely submitted specimen

2. SP: Kidney, right; total nephrectomy

Tumor Type:

Renal cell carcinoma - Papillary type

Type 2

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 3.8 cm.

Local Invasion (for renal cortical types):

Involves renal hilar fat

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

[page 2 of 3]
[REDACTED]

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

3. SP: Soft tissue, perinephric; excision [REDACTED]
Fibroadipose tissue with fibrosis, fat necrosis and calcification; no tumor seen.
4. SP: Lymph nodes #2, paracaval; excision [REDACTED]
Lymph Nodes:
Not involved
Number of nodes examined: 7
Benign segment of ureter.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT

[REDACTED]

Gross Description:

[REDACTED]

1) The specimen is received fresh, labeled "paracaval lymph node" and consists of a 2.4 X 1.8 x 0.4 cm fragment of tan red tissue. No definite lymph nodes are identified. Entirely submitted.

Summary of sections:
U -- undesignated

[REDACTED]

2) The specimen is received fresh labeled "right kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 281.5 g in total. The kidney measures 7.9 x 5.2 x 5.0 cm. The attached ureter measures 2.4 cm in length and 0.4 cm in diameter. The attached renal vein measures 1.9 cm in length and 0.3 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. There is a 2.9 x 2.3 cm previous excision site at a kidney pole. The excision site is inked blue while the remainder of the kidney is inked black. The kidney is bivalved to reveal a 3.8 x 3.7 x 3.1 cm largely hemorrhagic and partially gold - tan tumor that is located in the hilar fat. Sections through the remainder of the kidney reveal pink-brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.6 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. Representative sections are submitted for [REDACTED] and for permanent sections. Photographs are taken.

Summary of sections:
UVM -- ureteral and vessel margins
T -- tumor
THF -- tumor with hilar fat
TSF -- tumor with sinus fat
TK -- tumor with adjacent kidney
TC -- tumor to capsule
K -- representative sections kidney
BX -- previous excision site

[REDACTED]

3) The specimen is received fresh for frozen section consultation, labeled "perinephric soft tissue stitch marks area of interest" and consists of a fragment of fibroadipose measuring 5.0 x 3.7 x 2.4 cm. The specimen is focally surfaced by a 3.5 x 1.0 cm fragment of fibromembranous tissue. The area around the stitch is inked black. The remainder of the specimen is inked blue. Cut surfaces show a 2.9 x 2.3 x 1.5 cm area of fat necrosis with a capsule. There are multiple surgical staples within the specimen. Representatively submitted for frozen section.

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Summary of sections:

FSC -- frozen section control

U -- additional representative sections

4) The specimen is received in formalin labeled "paracaval lymph nodes #2" and consists of a 3.2 x 2.0 x 0.3 cm irregular fibrofatty soft tissue fragment to include multiple pink tan fatty lymph nodes ranging from 0.4 cm up to 2.8 cm in greatest dimension. All identified lymph nodes and the remaining fibrous tissue is entirely submitted.

Summary of sections:

BLN-bisected lymph nodes

LN-lymph nodes

U - undesignated

Summary of Sections:

Part 1: SP: Lymph nodes, paracaval; excision

Block	Sect. Site	PCs
1	U	2

Part 2: SP: Kidney, right; total nephrectomy

Block	Sect. Site	PCs
1	BX	1
1	K	1
1	T	2
1	tc	1
1	THF	3
1	TK	2
1	TSF	2
1	uvm	3

Part 3: SP: Soft tissue, perinephric; excision

Block	Sect. Site	PCs
1	FSC	1
4	U	4

Part 4: SP: Lymph nodes #2, paracaval; excision

Block	Sect. Site	PCs
2	bln	2
2	ln	2
1	u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

3) FROZEN SECTION DIAGNOSIS: PERINEPHRIC SOFT TISSUE (FS): FIBROSIS AND CALCIFICATION (LIN)
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file f5263bc5-21a1-420d-9378-0efdf4e5cf8f (TCGA-BQ-5887.AAD105E0-56CC-4057-89FC-834CFF6F1567.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).